Somatic mutation profile of tumor specimen BA2060D (aliquot aq-BA2060D) from BEATAML1.0 case 2256, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.6 years (21,028 days).
Specimen BA2060D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40547300-4f49-4c1f-b1c3-293e852ad52c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2741D (Solid Tissue Normal), aliquot aq-BA2741D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9be6cc7f-3f0c-49c8-b860-b333aa76dff3

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Del 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK8 | c.5009C>A p.A1670E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66624028; called by muse, mutect2
- DLST | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- NFATC2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- RAD21 | c.1175_1176del p.C392Sfs*10 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel
- RFLNA | c.601C>A p.Q201K (on ENST00000546355 / NM_001365156.1; = p.Q120K on NM_181709.4) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- KIAA0100 | c.5664G>T p.L1888= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
